HCMI case HCM-SANG-0268-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/07a067d0-7dfc-4817-b4c5-9200da20a59f

Demographics
Sex at birth: male; Days to birth: -29,402 days (80.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.4; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS; Uicc clinical stage: Stage IIB; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIIB; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes; Vascular invasion type: Extramural.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Ulcerative Colitis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (6 samples)
- Sample HCM-SANG-0268-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HCM-SANG-0268-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0268-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0268-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0268-C18-85A-01D-A80T-32, HCM-SANG-0268-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
